Somatic mutation profile of tumor specimen MP2PRT-PAWADX-TMP1-A (aliquot MP2PRT-PAWADX-TMP1-A-1-0-D-A82M-36) from MP2PRT case MP2PRT-PAWADX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 3.9 years (1,407 days).
Specimen MP2PRT-PAWADX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ee49f64-e390-4a2d-9a2c-fc4ba2969d0b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAWADX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAWADX-NB1-A-1-0-D-A82M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b240757a-b1da-484f-b2d5-d6df503d70ea

The open-access MAF lists 34 somatic variants for this specimen: 23 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 10, Frame Shift Ins 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 34/267 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs730880471; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.3736C>T p.R1246C | Missense Mutation (SNP) | VAF 45/214 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.066); catalogued as rs202208717; called by muse, mutect2, varscan2
- DROSHA | c.2561C>T p.S854F | Missense Mutation (SNP) | VAF 31/247 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.706); catalogued as rs1559205; called by muse, mutect2, varscan2
- FRRS1 | c.1561G>A p.V521I | Missense Mutation (SNP) | VAF 62/283 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.857); catalogued as rs774713001, COSV54921881; called by muse, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 36/232 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RAET1L | c.538A>G p.M180V | Missense Mutation (SNP) | VAF 40/439 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.038); catalogued as COSV53953772; called by muse, mutect2
- SERPINA5 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 51/195 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.055); catalogued as rs757910699; called by muse, mutect2, varscan2
- CHD6 | c.1934A>C p.E645A | Missense Mutation (SNP) | VAF 56/330 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNER | c.566T>A p.M189K | Missense Mutation (SNP) | VAF 13/191 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.139); called by muse, mutect2
- GFPT2 | c.705T>G p.C235W | Missense Mutation (SNP) | VAF 13/381 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.049); called by muse, mutect2
- IGHV3-66 | c.345_346insCC p.R116Pfs*? | Frame Shift Ins (INS) | VAF 8/64 reads (13%) | called by mutect2, varscan2
- IGHV4-61 | c.353_354insCCCAAAGG p.R118Sfs*? | Frame Shift Ins (INS) | VAF 14/114 reads (12%) | called by pindel, varscan2
- IGLV4-69 | chr22:22031468 ATTCAC>CAGGG | Missense Mutation (DEL) | VAF 18/165 reads (11%) | called by pindel, varscan2*
- KCNQ1 | c.386T>A p.V129D | Missense Mutation (SNP) | VAF 16/364 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2
- LRP1 | c.9514C>T p.R3172C | Missense Mutation (SNP) | VAF 16/444 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2
- MYL6 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 20/387 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); called by muse, mutect2
- NAV3 | c.6164C>T p.S2055L (on ENST00000397909 / NM_001024383.2; = p.S2033L on NM_014903.6) | Missense Mutation (SNP) | VAF 31/322 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PALMD | c.1387T>A p.Y463N | Missense Mutation (SNP) | VAF 104/296 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- PDZD2 | c.2908G>T p.A970S | Missense Mutation (SNP) | VAF 66/365 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- WNT1 | c.43C>G p.L15V | Missense Mutation (SNP) | VAF 63/558 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF343 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 13/407 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZNF449 | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 52/573 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.01); called by muse, mutect2
- ZNF714 | c.893C>T p.S298L | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AC013470.2 | c.168T>C p.N56= | Silent (SNP) | VAF 33/195 reads (17%) | called by muse, mutect2, varscan2
- CRACD | c.849G>A p.A283= | Silent (SNP) | VAF 40/512 reads (8%) | catalogued as rs576383014; called by muse, mutect2
- EZHIP | c.747C>T p.R249= | Silent (SNP) | VAF 31/605 reads (5%) | catalogued as COSV57957300; called by muse, mutect2
- FAM107A | c.111C>A p.P37= | Silent (SNP) | VAF 73/350 reads (21%) | called by muse, mutect2, varscan2
- KCNB2 | c.138C>T p.H46= | Silent (SNP) | VAF 60/352 reads (17%) | catalogued as rs550252460, COSV73051460; called by muse, mutect2, varscan2
- MEI1 | c.552G>A p.L184= | Silent (SNP) | VAF 30/226 reads (13%) | catalogued as rs887035686; called by muse, varscan2
- MIB1 | c.1614C>T p.V538= | Silent (SNP) | VAF 14/396 reads (4%) | called by muse, mutect2
- NBEA | c.7002G>A p.L2334= | Silent (SNP) | VAF 8/188 reads (4%) | called by muse, mutect2
- SMIM1 | c.147C>T p.I49= | Silent (SNP) | VAF 46/362 reads (13%) | catalogued as rs765223124, COSV53901035; called by muse, mutect2, varscan2
- ZFHX4 | c.3906G>A p.E1302= | Silent (SNP) | VAF 15/348 reads (4%) | catalogued as COSV99265658; called by muse, mutect2
- Z99774.2 | chr22:26668824 T>C | 5'Flank (SNP) | VAF 22/328 reads (7%) | catalogued as rs1038090136; called by muse, mutect2
